Surgical pathology report (de-identified scan), TCGA case TCGA-KR-A7K7, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site University Of Michigan, specimen TCGA-KR-A7K7-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

PAGE #: 4

BIRTHDATE:

SEX: F

ADM DATE:

OPER DATE:

PROCEDURE: SPDX

(1) Uterus, excision: focal residual adenocarcinoma in-situ of endometrium.
Adenomatous hyperplasia of endometrium. Squamous metaplasia of cervix.

EC0-0-3
Carcinoma, hepatocellular
817013

Site: Liver C22.0

(2) Ovaries and fallopian tubes, excision: tubo-ovarian adhesions.
Follicular cysts.

gw 8/27/13

(3) Right interiliac and external iliac lymph nodes, excision: four lymph
nodes, all negative for neoplasm.

Code:

Service:

FC: 23209

M-72000 M-72420 M-81403 T-82000

OPER DATE:

PROCEDURE: SPHS

History with mass in left hepatic lobe. Tissue Submitted: Left lateral segment
liver.

PROCEDURE: SPGD

1. "Left lateral segment of liver" Received in formalin in an extra large
container is a 2040 gram the lobe of liver designated left and is 20 x 8 x 10
cm. Extending from the anterior aspect is a protuberant partially encapsulated
massive lesion, 14 x 13 x 10.2 cm. Capsule surrounding the liver segment is
tan and focally nodular. The margin of resection is inked blue. Cut surface of
the liver is a tan-brown nodular tissue. It is remarkable for the
aforementioned mass that has a hemorrhagic necrotic red-tan softened cut
surface with bright focal areas of fat necrosis. A central yellow-gray scar is
identified. The tumor is 2.2 cm away from the margin of resection. It extends
to the capsule and appears to press into the attached liver parenchyma. No
other lesions are identified. Photographs have been taken.

1A. Tumor to margin of resection.

1B. Tumor to liver and capsule.

1C. Tumor to necrotic area.

1D. Possible viable tumor to liver.

1E. Tumor to capsule.

1F. Normal liver.

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PAGE #: 5
SEX: F
ADM DATE:

OPER DATE:

PROCEDURE: SPMI

LIVER: HEPATOCELLULAR CARCINOMA
=====

WAS THE TUMOR PREVIOUSLY TREATED?: No

TUMOR TYPE: Ordinary

SINGLE OR MULTIPLE MASSES: Single

MAXIMUM DIAMETER OF LARGEST MASS: 14 cm

ARE THE MARGINS OF RESECTION FREE OF TUMOR?: Yes

VASCULAR INVASION?: Yes

INVASION THROUGH THE CAPSULE TO THE SEROSAL SURFACE?: No

LYMPH NODE METASTASES?: Unknown

DISTANT METASTASES?: Unknown

IS THE LIVER CIRRHOTIC?: Yes

pT2 NX

PROCEDURE: SPDX

VERIFIED BY:

1. Left lateral segment of liver, excision: Hepatocellular carcinoma (14cm),
with vascular invasion. Margins free. Please see template for full details.
Background liver with cirrhosis and steatohepatitis.

I, _____ the signing staff pathologist, have personally
examined and interpreted the slides from this case.

Code:

Source: NCI Genomic Data Commons file d3029de1-eae7-45d4-9f22-c879035b5318 (TCGA-KR-A7K7.8CE97410-9210-4B15-97FE-E61722535975.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).